Somatic mutation profile of tumor specimen TCGA-XK-AAJA-01A (aliquot TCGA-XK-AAJA-01A-11D-A41K-08) from TCGA case TCGA-XK-AAJA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,771 days).
Specimen TCGA-XK-AAJA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf216ba-bb4d-4881-8698-b57504d5ae58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAJA-10A (Blood Derived Normal), aliquot TCGA-XK-AAJA-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4983052-9a06-4802-a8c6-659b44d04445

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Frame Shift Del 3, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99684921; called by muse, mutect2, varscan2
- ADAMTS20 | c.4151T>A p.I1384K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.692); catalogued as COSV101166115; called by muse, mutect2, varscan2
- ANGPTL6 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs369036998; called by muse, mutect2, varscan2
- ANXA5 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99634252; called by muse, mutect2
- ARCN1 | c.1143G>C p.W381C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99873514; called by muse, mutect2, varscan2
- BTN3A3 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.524); catalogued as COSV99764797; called by muse, mutect2, varscan2
- CCNL2 | c.888del p.E297Kfs*56 | Frame Shift Del (DEL) | VAF 44/132 reads (33%) | catalogued as COSV68766547; called by mutect2, pindel, varscan2
- COL22A1 | c.3398A>G p.D1133G | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761606988, COSV100276967; called by muse, mutect2, varscan2
- ECE2 | c.888+2T>C p.X296_splice (on ENST00000357474 / NM_001100120.2; = p.X221_splice on NM_001037324.3) | Splice Site (SNP) | VAF 11/60 reads (18%) | catalogued as rs771052643, COSV100668466; called by muse, mutect2, varscan2
- EEFSEC | c.442del p.I148* | Frame Shift Del (DEL) | VAF 40/186 reads (22%) | catalogued as rs1294626592; called by mutect2, pindel, varscan2
- EIF2B5 | c.2139G>T p.R713S (on ENST00000647909; = p.R705S on NM_003907.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV99889071; called by muse, mutect2, varscan2
- EPHB1 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101212832; called by muse, mutect2
- FBN3 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV99560240; called by muse, mutect2
- MAGEB6 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs750398271, COSV100983679, COSV66872128; called by muse, mutect2, varscan2
- MBIP | c.575del p.N192Ifs*20 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | catalogued as rs1487310665; called by mutect2, pindel, varscan2
- MKRN1 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99751495; called by muse, mutect2
- MSH2 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1060502021, CD066378, CD076833, COSV51887622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBPF1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs768221719, COSV101236256, COSV101236433, COSV67426530; called by muse, mutect2, varscan2
- PCDHB6 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs891979677, COSV50689851, COSV50706884; called by muse, mutect2, varscan2
- RHBDL2 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV100008348; called by muse, mutect2, varscan2
- RTP1 | c.464A>C p.D155A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV100398685; called by muse, mutect2, varscan2
- RYR2 | c.2706G>T p.W902C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100767330; called by mutect2, varscan2
- SAFB | c.2292G>T p.R764S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV99412581; called by muse, mutect2, varscan2
- SCAPER | c.2367A>T p.E789D | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100237594; called by muse, mutect2, varscan2
- SCN5A | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs397517951, COSV100347013; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- SEPTIN5 | c.1098G>A p.M366I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs1331363082, COSV100820377; called by muse, mutect2
- SLC38A1 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV67063098; called by muse, mutect2, varscan2
- SPTBN4 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs372472584; called by muse, mutect2, varscan2
- TRMT11 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.493); catalogued as COSV100543101; called by muse, mutect2, varscan2
- TXNRD1 | c.1576A>C p.T526P (on ENST00000525566 / NM_001093771.3; = p.T428P on NM_003330.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100723351; called by muse, mutect2
- ZNF420 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749365359, COSV100421194; called by muse, mutect2, varscan2
- ANO5 | c.591G>A p.E197= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV100201582; called by muse, mutect2, varscan2
- CACNA1I | c.2376G>A p.T792= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs374658074; called by muse, varscan2
- CSMD1 | c.9372C>T p.C3124= (on ENST00000520002; = p.C3123= on NM_033225.6) | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1169751583, COSV100145194, COSV59370198; called by muse, mutect2, varscan2
- CUBN | c.3165T>C p.D1055= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100912247; called by muse, mutect2, varscan2
- FNDC7 | c.960G>A p.V320= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV99600998; called by muse, mutect2, varscan2
- KLHL2 | c.759A>G p.E253= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV99899768; called by muse, mutect2
- MARK3 | c.2115G>A p.G705= (on ENST00000429436 / NM_001128918.3; = p.G681= on NM_002376.6) | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99357975; called by muse, mutect2, varscan2
- OR9G4 | c.75G>A p.P25= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs755550044, COSV57248348; called by muse, mutect2
- PCDHGB6 | c.1533C>T p.S511= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV53944498; called by muse, mutect2, varscan2
- PXDNL | c.1692G>A p.T564= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs370914039, COSV100682381; called by muse, mutect2, varscan2
- RCAN3 | c.552T>C p.Y184= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs756630635, COSV100980324; called by muse, mutect2, varscan2
- TMPRSS2 | c.1209T>G p.L403= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100151300; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27699C>T | Intron (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100942476; called by muse, mutect2, varscan2
